Surgical pathology report (de-identified scan), TCGA case TCGA-39-5031, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5031-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

with left upper lobe lung nodule squamous cell carcinoma.

Specimens Submitted:

- 1: SP: Part of 6th rib ()
- 2: SP: Level 9 lymph node ()
- 3: SP: Level 11 intralobar lymph node ()
- 4: SP: Level 5 lymph node ()
- 5: SP: Level 12 lymph node ()
- 6: SP: Left upper lobe ()

DIAGNOSIS:

- 1) RIB, PART OF 6TH; EXCISION:
- BENIGN BONE AND BONE MARROW.
- 2) LYMPH NODE, LEVEL IX; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 3) LYMPH NODES, LEVEL XI INTRALOBAR; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 4) LYMPH NODE, LEVEL V; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 5) LYMPH NODES, LEVEL XII; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 6) LUNG, LEFT UPPER LOBE; LOBECTOMY:
- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, OF LEFT UPPER LOBE.
- THE TUMOR GREATEST DIAMETER IS 1.9 CM.
- LYMPHOVASCULAR INVASION IS PRESENT.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE PLEURA IS FREE OF TUMOR.
- A SEPARATE FOCUS OF BRONCHIOLOALVEOLAR CARCINOMA IS IDENTIFIED IN SECTION AWAY FROM THE MAIN TUMOR, MEASURING 0.5 CM IN GREATEST DIAMETER.
- MULTIPLE FOCI OF ATYPICAL ADENOMATOUS HYPERPLASIA ARE SEEN.
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITIES: EMPHYSEMATOUS

** Continued on next page **

[page 2 of 4]
----- Page 2 of 4
CHANGES, FOCAL ORGANIZING PNEUMONIA AND CARCINOID TUMORLETS.

- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC
NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): PERIBRONCHIAL:
0/4.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

1). The specimen is received in formalin, labeled "Part of sixth rib" and
consists of a segment of rib bone measuring 1.1 x 0.9 x 0.5 cm. One end is
inked in black, and the other is inked in green. The specimen is bisected
and reveals homogeneous red-tan bony cut surface with no discrete
abnormalities grossly noted. The cortical surface appears intact. The
specimen is bisected and submitted entirely, pending decal.

Summary of sections:
U-undesignated

2). The specimen is received in formalin, labeled "Level 9 lymph node" and
consists of an anthracotic lymphoid fragment measuring 1.3 x 0.8 x 0.3 cm,
which is entirely submitted.

Summary of sections:
U-undesignated

3). The specimen is received in formalin, labeled "Level 11 intralobar
lymph node" and consists of three anthracotic lymphoid fragments ranging
from 0.2 to 0.8 cm, which are entirely submitted.

Summary of sections:
U-undesignated

4). The specimen is received in formalin, labeled "Level 5 lymph node" and
consists of a 0.8 cm anthracotic lymphoid fragment, which is entirely
submitted.

Summary of sections:
U-undesignated

** Continued on next page **

[page 3 of 4]
5). The specimen is received in formalin, labeled "Level 12 lymph node" and consists of three anthracotic lymphoid fragments ranging from 0.4 to 0.9 cm which are entirely submitted.

Summary of sections:
U-undesignated

6.) The specimen is received fresh and is labeled, "left upper lobe". It consists of a 17 x 10 x 2.5 cm lung lobe with attached bronchus and blood vessels straddled by multiple staple lines, which weighs 230 grams following fixation. The specimen is received with an incision. The attached bronchus measures 0.6 cm in length. The pleural surface is smooth and glistening. The pleural surface is inked black. Serial sectioning reveals a 1.5 x 1.5 x 1.2 cm white, tan, stellate tumor. The tumor has irregular borders. The tumor is situated in the peripheral lung parenchyma, located 5 cm from the bronchial margin and 1.5 cm from the closest staple line. The tumor is subpleural with a puckered overlying pleural surface. The tumor grossly does not involve the bronchus. The bronchial mucosa is smooth and glistening. Peribronchial anthracotic lymph nodes are identified and are submitted. The uninvolved lung parenchyma shows congestion. Representative sections are submitted. TPS is submitted and photographs are taken.

Summary of sections:
BM -- bronchial margin.
VM -- vascular margin.
SM -- staple margin.
T -- tumor
RA - random lung parenchyma at least 3 cm away from main tumor
RC - random lung parenchyma close to tumor (within 3 cm of main tumor)
LN -- lymph nodes

Summary of Sections:

Part 1: SP: Part of 6th rib

Block	Sect.	Site	PCs
1	u		1

Part 2: SP: Level 9 lymph node

Block	Sect.	Site	PCs
1	u		1

Part 3: SP: Level 11 intralobar lymph node

Block	Sect.	Site	PCs

** Continued on next page **

[page 4 of 4]
1 u 1

Part 4: SP: Level 5 lymph node [REDACTED] [REDACTED])

Block	Sect.	Site	PCs
1		u	1

Part 5: SP: Level 12 lymph node [REDACTED]

Block	Sect.	Site	PCs
1		u	11

Part 6: SP: Left upper lobe

Block	Sect.	Site	PCs
1		BM	1
1		LN	1
3		RA	3
3		RC	3
1		SM	1
4		T	4
1		VM	1

**** End of Report ****

Source: NCI Genomic Data Commons file 92f57b42-314a-4e89-9b59-114b8a796611 (TCGA-39-5031.45179EC8-08FE-4E6C-B5B3-E2EF7711B710.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).